Gene-level copy-number profile of tumor specimen TCGA-GN-A26A-06A from TCGA case TCGA-GN-A26A, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.5 years (23,906 days).
Specimen TCGA-GN-A26A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.f6c9c868-2d9d-4793-9ec7-a73bdc5ef314.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A26A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c37672f-a697-440f-b2b3-1e2f6cd16e59

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 126; copy number 2: 13,690; copy number 3: 26,661; copy number 4: 14,474; copy number 5: 3,229; copy number 6: 1,083; copy number 7: 277; copy number 8: 274; copy number 9: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A26A-06A-11D-A192-01): tumor purity 0.48, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 556 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–150,809,577, 276 genes, copy number 7 (broad region; genes not listed).
- chr1:150,812,591–150,812,698, 1 gene, copy number 7: RNU6-1309P.
- chr1:151,870,866–155,018,522, 175 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr1:181,962,889–182,982,318, 32 genes, copy number 8: AL391477.1, ZNF648, AL355482.1, AL355482.2, LINC01344, AL390856.1, YPEL5P1, RNU6-152P, AL513480.1, EIF1P3, GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P.
- chr1:193,304,745–193,465,198, 2 genes, copy number 9 (within-gene range 6–9): LINC01031, AL138778.1.
- chr1:193,678,894–193,757,267, 3 genes, copy number 9: AL357793.1, AL357793.2, RPL23AP22.
- chr1:243,917,402–244,971,088, 25 genes, copy number 8: LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5, DESI2, AL451007.1, AL451007.3, AL451007.2, BX323046.2, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1.
- chr1:245,749,342–247,210,856, 42 genes, copy number 8 (within-gene range 5–8): SMYD3, AC118555.1, SMYD3-AS1, CHCHD4P5, RNU6-1283P, SMYD3-IT1, Y_RNA, AL356583.1, LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2, AHCTF1, ZNF695, ZNF670-ZNF695, AL512637.2, ZNF670, AL512637.1, AL627095.1, ZNF669, AL627095.2, C1orf229, FGFR3P6, ZNF124, AL390728.3, AL390728.2, AL390728.6, AL390728.4, MIR3916, RNA5SP82.

Autosomal genes at a single copy (total copy number 1): 126. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
